Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NJ-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN NINE (9) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SEVEN (7) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8 WITH TERTIARY GLEASON PATTERN 3 AND 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.2 CM.
- C. THE CARCINOMA INVOLVES 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c NO MX.
- K. TNM HISTOLOGIC GRADE = G4.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 8
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 80%
WEIGHT OF PROSTATE: 43.14gm
TUMOR SIZE: Maximum dimension: 1.2 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 16
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

66CF IAD-0-3
Adenocarcinoma, acinar
path 8/40/13
Adenocarcinoma NOS 8/40/13
Site Prostate NOS
C61.9
J1 9/24/13

Source: NCI Genomic Data Commons file f6b27718-7e6e-44f3-8212-18f788bd4bff (TCGA-EJ-A7NJ.B6D55BEF-A9C3-4092-AE17-FB6790EC65AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).